Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AD3D, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AD3D-TTM1-A (Metastatic).

[page 1 of 18]
Results

Surgical Pathology (Order [REDACTED])

Result DataACCESSION
[REDACTED]

Result Date [REDACTED] +23

Component Results

Component

Clinical History

Malignant neoplasm ileocecal valve. Please note difficult diagnosis poorly differentiated adenocarcinoma in lung, duodenum, ileocecal junction.

Gross Examination

+23

A. "Ileum through mid transverse colon". Received fresh and placed in formalin at [REDACTED] is a right hemicolectomy with transverse colectomy specimen with a 10 x 3.5 cm terminal ileum, 4 x 0.5 cm appendix, a 16 x 4 cm cecum and right colon, and a 16 x 3.5 cm transverse colon. An unremarkable 18 x 17 x 1.5 cm omentum is attached. The opened specimen demonstrates at the ileocecal valve comprising approximately 75% and occluding the lumen, a 7 x 6 x 6 cm exophytic, sessile polypoid mass, 7.5 cm to the proximal margin, and greater than 20 cm to the distal margin. There is associated serosal retraction but no gross involvement of the serosa by tumor. Cut surfaces demonstrate the muscularis propria drawn into the tumor; however, tumor involvement of the muscularis propria cannot be determined grossly. The entire stalk with associated tumor is submitted. Distance to the nearest radial margin (ileocolic vascular pedicle) is 7 cm. Tattooing ink is noted adjacent to the mass. The remaining mucosal surface is free of other gross abnormalities. Twenty-one lymph nodes are dissected from the pericolon soft tissue ranging from 0.1 to 2 cm in greatest dimension. Representative sections are submitted in 18 blocks as follows:

BLOCK SUMMARY:

A1-8- entire mass stalk
A9- representative proximal margin
A10- representative distal margin
A11- radial margin
A12- appendix
A13-14- six lymph nodes in each block
A15- three lymph nodes
A16- four lymph nodes
A17-18- one lymph node in each block, each serially sectioned

Microscopic Examination

Microscopic examination is performed.

Diagnosis

A. ILEUM THROUGH MID-TRANSVERSE COLON, PARTIAL COLECTOMY:

METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA, MOST COMPATIBLE WITH LUNG PRIMARY. SEE COMMENT.

[page 2 of 18]
Tumor site: INVOLVES ILEOCECAL VALVE, ERODING THROUGH MUCOSA AND EXTENDING THROUGH MUSCULARIS PROPRIA

Tumor size: 7 X 6 X 6 CM.

Margins:

Proximal NEGATIVE.
Distal NEGATIVE.
Deep (Radial) or mesenteric: NEGATIVE.
Closest Margin: Radial, 7 CM.

Regional Lymph Nodes: TWENTY LYMPH NODES, NEGATIVE FOR MALIGNANCY.
(0/20).

COMMENT: The tumor is characterized by large pleomorphic epithelial cells with at least a moderate amount of cytoplasm, with some tumor cells showing rhabdoid features. No obvious glandular or squamous differentiation is seen. The overlying and adjacent intestinal mucosa shows no evidence of dysplasia to suggest this is a primary intestinal tumor, and the histologic appearance is identical to that seen in the patient's prior endoscopic biopsy (see [REDACTED]). Immunostains are performed, with appropriate controls examined. The tumor cells are positive for pan-keratin, vimentin, TTF-1 (nuclear staining), CD10, and shows rare cells reactive for CK7. The tumor cells are negative for napsin-A, CK20, CDX-2, CA19-9, S100, HMB45, p63, myogenin, myoglobin, RCC, CD30, CD5, SMA, desmin, chromogranin, synaptophysin, and calcitonin. This immunophenotype, in conjunction with the histologic features, supports the above diagnosis.

[REDACTED] has also reviewed this case and concurs.

Comment:

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Lab and Collection

Surgical Pathology on [REDACTED] +23

Result Date - [REDACTED]

Lab and Collection

+23

Surgical Pathology (Order [REDACTED] on [REDACTED] - Lab and Collection Information

Result Information

Abnormality	Status	Priority	Source
	+23		
	Final result [REDACTED]	Routine	

Authorizing Provider Information

Name: [REDACTED] Fax: [REDACTED]

Phone: [REDACTED] Pager: [REDACTED]

[page 3 of 18]
Clean AP Report Link

+23

SPECIMEN TO PATHOLOGY (Order [REDACTED] on [REDACTED])

Surgical Pathology (Order [REDACTED])

Date: [REDACTED] +23

Pathology and Cytology

Department: [REDACTED]

Order: [REDACTED]

Ordering/Aut [REDACTED]

Order Information

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

[REDACTED]

None

[REDACTED]

None

Order Details +23

+23

Frequency

Duration

Priority

None

None

Routine

Encounter

View Encounter

Reprint Requisition

SPECIMEN TO PATHOLOGY (Order [REDACTED] +23)

Collection Information

Specimen ID/Accession: [REDACTED]

Collection Date/Time: [REDACTED] +23

Order Provider Info

		Office phone	Pager/beeper	E-mail
Ordering User	Lab Conversion Interface	--	--	--
Authorizing Provider	[REDACTED]	--	--	--
Attending Provider	[REDACTED]	--	--	--

No order transmittal information available.**Order may not have completed order transmittal.**

[page 4 of 18]
CT abdomen pelvis with contrast

Status: Final result

Study Result

Verified

Exam: CT abdomen and pelvis with contrast

Date: [REDACTED] +4

Indication: Evaluate Hypermetabolic Mass on PET/CT

Comparison [REDACTED] reference only chest, [REDACTED] the CT
-14 +4

Technique: CT imaging was performed of the abdomen and pelvis following the uncomplicated administration of intravenous contrast (Isovue-300, 150 mL at 3 mL/sec). Iodinated contrast was used due to the indications for the examination. If IV contrast material had not been administered, the likelihood of detecting abnormalities relevant to the patients condition would have been substantially decreased. The most recent serum creatinine is 1.0 mg/dL. Coronal reformatted images were generated and reviewed to improve anatomic localization and optimize lesion detection.

Findings:

Lung bases colon

Small right and trace left pleural effusions are partially visualized. Known large right pulmonary mass is not seen within these images.

Abdomen:

A hypermetabolic region in the right hemiabdomen seen on prior PET/CT corresponds to a soft tissue mass within the transverse colon with associated likely terminal ileal intussusception (series 5, image 38 and series 6, image 22). There is associated stretching of mesenteric vessels in this region secondary to the intussusception. Additional hypermetabolic region anterior to the left kidney did not demonstrate a definite mass. Mild distal small bowel dilatation without obstruction. Several mildly enlarged right lower quadrant mesenteric lymph nodes.

There is an ill-defined low-attenuation lesion in the periphery of the right hepatic lobe that measures 1.0 x 0.9 cm (series 5, image 13). No additional focal hepatic lesions are seen.

There are no calcified gallstones or biliary ductal dilatation.

The spleen is unremarkable.

The pancreas is homogeneous without focal lesion or ductal dilatation.

There are bilateral symmetric nephrograms with no evidence for hydronephrosis or mass lesions.

The adrenal glands are normal.

There is no significant abdominal lymphadenopathy or ascites. No bowel obstruction is seen. No pneumatosis or free intraperitoneal air.

[page 5 of 18]
Pelvis

There is no pelvic lymphadenopathy or mass. No free fluid. The pelvic organs are unremarkable.

Bones: There are no aggressive appearing osseous lesions.

Impression:

1. Soft tissue mass within the transverse colon with associated terminal ileal-colonic intussusception, which corresponds hypermetabolic mass seen on prior PET/CT. This is most worrisome for primary colonic cancer (mass in the terminal ileum acting as a lead point is less likely). Additional hypermetabolic area seen on prior PET anterior to the left kidney demonstrates no definite CT correlate, and may be within the bowel wall.

2. Indeterminate right hepatic lobe lesion.

3. Bilateral pleural effusions are only partially visualized. Known right lung mass is not seen on these images.

I have reviewed the images and concur with the above findings.

Imaging

CT abdomen pelvis with contrast

Imaging Information

Signed by

Date/Time

Phone

Pager

Exam Information

Status
Final [99]

Exam
Begun

Exam
Ended

PACS Images

Show images for CT abdomen pelvis with contrast

External Result Report

External Result Report

Encounter

View Encounter

CT abdomen pelvis with contrast

Status: Final result

Supplies

[page 6 of 18]
No case/log ID found

CT abdomen pelvis with contrast (Order

Date: [REDACTED] +4
Department: [REDACTED]
Ordering/Au [REDACTED]

Imaging

Order: [REDACTED]

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
[REDACTED] +4	None	[REDACTED] +4	None

Order Details

Frequency	Duration	Priority	Order Class
None	None	Routine	Normal

Collection Information

Collected: [REDACTED] +4 Resulting Agency: [REDACTED]

Order Provider Info

Ordering User	Rad Conversion Interface	Office phone	Pager/beeper	E-mail
[REDACTED]	[REDACTED]	--	--	--

Reprint Requisition

CT ABDOMEN PELVIS W CONTRAST (Order [REDACTED] +4

[page 7 of 18]
PATIENT:
DOB:
PATIENT PHONE:
MRN:
PHYSICIAN:
DATE: -14

EXAM: CT CHEST WITH CONTRAST AND I-STAT CREATININE

HISTORY: Abnormal mass in the chest. Productive cough and low grade fever.

COMPARISON: None.

TECHNIQUE: Following intravenous contrast, axial CT images of the chest were obtained from the thoracic inlet through the upper abdomen.

I-STAT CREATININE: 1.0 mg/dL, estimated GFR 83.

CONTRAST: 100 Isovue-300, IV.

FINDINGS:

Lungs/Pleura: There is a large lobulated heterogeneous enhancing mass of the lateral right upper lobe which measures 8.4 x 6.8 x 8 cm in greatest dimensions. The mass abutts the pleural surface. There are low attenuation and heterogeneously enhancing components within this mass. This large mass is highly suspicious for primary lung neoplasm or other neoplasm such as lymphoma. There is minimal adjacent atelectasis and ground-glass opacity related to this mass. No additional pulmonary parenchymal masses or nodules are identified.

Mediastinum: There is a 2.7 x 2.4 cm low attenuation right hilar mass, suspicious for a metastatic lymph node. No left hilar adenopathy is noted. No mediastinal adenopathy is noted. No mediastinal mass is seen. The heart size and aorta are normal.

Chest Wall: No axillary adenopathy is identified. No definite additional chest wall masses are noted. Involvement by the large pulmonary mass with the chest wall cannot be excluded because of artifact from contrast within the right subclavian and axillary vein. No destructive osseous lesions are seen. No fractures are seen.

IMPRESSION: Large lobulated heterogeneously enhancing peripheral right upper lobe lung mass with associated abnormal right hilar adenopathy, highly suspicious for primary lung neoplasm or other neoplasm.

[page 8 of 18]
Fax Server

Patient:

MRN:

EXAM: CT CHEST WITH CONTRAST AND I-STAT CREATININE

This document has been electronically reviewed and signed.

[page 9 of 18]
Progress Notes**Progress Notes Info**

Author	Note Status	Last Update User	Last Update Date/Time
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]

+571

Progress Notes

Patient [REDACTED]

Dictated Rpt: Final [REDACTED] +268

TOP Interval Note

Patient Profile:**Problem List:**

1. 9 cm epigastric mass by physical exam with PET scan showing transverse colon large mass with small bowel intussusception with no tissue diagnosis.
2. Right upper lobe 8 cm mass with extrinsic compression of the right upper lobe bronchus. Washings from right upper lobe bronchus are negative; however, an endobronchial ultrasound biopsy of a level 11 lymph node returned poorly differentiated cancer TTF negative.
3. Severe anemia with a hemoglobin in the 5 range with dark bowel movements. Also positive history of food intolerance of oily foods and narrow caliber bowel movements which are new over the past two months.

Allergies:

No known drug allergies.

Insurance:**History of Present Illness:**

This is a 53 year old Chinese ethnic man who was in good health and exercising running four miles three times per week until [REDACTED] when he developed progressive fatigue. By early [REDACTED] he had developed a cough and fatigue. He saw his local doctor who put him on some antibiotics by mid [REDACTED]. The cough persisted. Again he visited his local doctor in late December. He had course of steroids and a second antibiotic but cough persisted. The fatigue was getting worse. On [REDACTED] he had a chest x-ray which showed a large right upper lung mass. He was admitted to [REDACTED] on [REDACTED] where he has a

[page 10 of 18]
PET scan which showed increased FDG in an 8 cm right upper lobe mass with an SUV of 19. It showed bilateral pleural effusions worse on the right than the left with an SUV of 1.9. It showed a right hilar enlarged lymph node 2.6 cm with an SUV of 5 and it showed a large abdominal mass with an elevated SUV. He had a hemoglobin of 5. He was transfused. He had a bronchoscopy on [REDACTED] which +0 showed extrinsic compression of the right upper lobe bronchus. No endobronchial tumor. Washings were negative. He had endoscopic bronchial ultrasound biopsy of the right level 11 lymph node which returned positive for poorly differentiated cancer TTF negative. The patient was discharged and is in my clinic today for counseling regarding treatment of his right upper lobe lung mass with presumptive transverse colon tumor which may be his primary. He is fully ambulatory but fatigued. ECOG performance is equal to 1.

Past Medical History:

1. Tonsillectomy in [REDACTED] ~-17554
2. Colectomy for metastatic lung cancer, ostomy [REDACTED] ~+9

Family History:

[REDACTED]

Social History:

He has never smoked and never drank alcohol.

Interval History:

Patient has received 10 courses of Pemetrexed, Cisplatin and Bevacizumab through [REDACTED] Today he is in clinic for #11 treatment. He is not short of breath. He has gained weight. He is tolerating diet. He is exercising daily.

Medications: (This list was reviewed with patient in clinic today and there are no changes.)

1. Ferrous sulfate 325 mg b.i.d.
2. Lovaza two capsules for cholesterol daily
3. Centrum Silver once daily
4. Simvastatin 20 mg once daily
5. Dexamethaxone 4 mg b.i.d. x3 days starting day prior to each chemotherapy
6. Folic acid 1 mg daily
7. Ondansetron 8 mg b.i.d. x3 days post chemotherapy
8. Prochlorperazine 10 mg q6h p.r.n. nausea
9. Folic acid 1 mg p.o. daily
10. Amlodipine 5 mg daily

Physical Examination:

Constitutional: This is an alert man who has gained weight and looks strong and normal.

Skin: There is no icterus, purpura or rash noted.

HEENT: PERRLA, EOME. Oropharynx clear.

Neck: Supple without JVD or thyromegaly.

Lymph Nodes: No lymphadenopathy.

Lungs: Lung are clear to auscultation bilaterally.

Cardiac: RRR without murmur, rub, gallop, or edema.

Abdomen: He has a left lower quadrant ileostomy. The ostomy bud is pink. There is some soft brown stool in the bag. Abdomen is soft and nontender.

Neurologic: Alert and oriented x 4. CNII-XII intact. Otherwise normal sensory, cerebellar, and strength exam.

[page 11 of 18]
Laboratory/Radiology Data:

Automated blood count and chemistries from today are normal.

PET performed yesterday, shows his right upper lobe mass continues to shrink.

His mediastinal lymph nodes are totally normalized and his left adrenal mass continues to shrink, left adrenal measuring 1.5 cm, right upper lobe measuring 5 cm.

Assessment/Plan:

1. T3N2M1 poorly differentiated adenocarcinoma in lung metastatic to duodenum and ileocecal junction.

- A. 9 cm epigastric mass by physical exam with PET scan showing transverse colon large mass with small bowel intussusception.
- B. Right upper lobe 8 cm mass with extrinsic compression of the right upper lobe bronchus. Washings from right upper lobe bronchus are negative; however, an endobronchial ultrasound biopsy of a level 11 lymph node returned poorly differentiated cancer TTF negative. PET scan indicates enlarged hypermetabolic paratracheal nodes.
- C. Severe anemia with a hemoglobin in the 5 range with dark bowel movements. Also positive history of food intolerance of oily foods and narrow caliber bowel movements which are new over the past two months.
- +16 D. Colonoscopy shows a 20 cm mass from the transverse colon extending proximally to the cecum and gastroscopy shows a suspect metastases in the third portion of the duodenum 1 cm in size.
- E. Ileum through mid-transverse colon, partial colectomy for a metastatic poorly differentiated adenocarcinoma, most compatible with lung primary based on IHC stains.
- +42 F. Brain MRI negative.
- G. ALK mutation negative. EGFR mutation negative. K-RAS negative.
- +9 H. hemicolectomy removal of a large transverse colon mass and terminal ileum interception with tumor.
- +84 I. after two courses of Pemetrexed and Cisplatin, he has stable disease in lung and left adrenal. However, clinically, his cough has resolved. He is eating and gaining weight and his strength is improved.
- +135 J. after four courses of Pemetrexed, platinum and bevacizumab the patient has an excellent 30% partial response in dominate right upper lobe mass, left adrenal mass and right mediastinal lymph nodes when compared to prior CT scan of [REDACTED].
- ~+69 His sense of well being is improving. His gaining weight. He is functioning normally and exercising.
- +198 K. after seven courses of pemetrexed and cisplatin with bevacizumab, the patient has another 20% shrinkage of his dominant left upper lobe mass and left adrenal mass. His intra-abdominal disease was resected in [REDACTED].
- +240 L. the patient to receive his tenth course of pemetrexed, cisplatin and bevacizumab.
- +268 M. continued partial response with disease limited to two sites namely a 5 cm right upper lobe mass and a 1.5 cm left adrenal mass. All mediastinal lymph nodes are normalized by PET after ten courses of Pemetrexed, Cisplatin and Bevacizumab.

2. Oncology plan. Plan will be to administer #11 treatment with Pemetrexed 500 mg/m², Cisplatin 75 mg/m² and Bevacizumab 1 mg/kg. Patient will see [REDACTED]

[page 12 of 18]
[REDACTED]

our chest surgeon to entertain 1/3 possible courses:

A. One option is staged resection, which could include right upper lobectomy, wait one month then left adrenalectomy with reconnection of his ileostomy and colostomy. This would render him disease free and then another 12 months of maintenance Pemetrexed and Bevacizumab in an adjuvant fashion. If he had positive mediastinal disease, post operative thoracic radiation to the mediastinal lymph nodes.

~+344 B. Second option, if he is deemed not to be a surgical candidate would be three more courses of Pemetrexed, Cisplatin or Bevacizumab with a repeat PET CT in [REDACTED] Treat to maximum response and then use maintenance Pemetrexed and Bevacizumab at a 4-6 week interval for another 12 to 24 months.

C. Third option, would be treat today and then operate one to two months from now when he is four to eight weeks out from Bevacizumab. Do the lung resection followed by adrenal resection in a staged fashion and if he rendered disease free, then observe.

+299

3. The patient will return to clinic on [REDACTED] for his 12th course of Pemetrexed, Cisplatin and Bevacizumab with Neulasta on [REDACTED] He +290 will have blood counts and chemistries on return. He will see [REDACTED] today to plan his surgical resection.

Issues concerning treatment and diagnosis were discussed. There were no barriers to understanding. The plan of treatment explanation was well received by the patient and family who then verbalized understanding.

[REDACTED]

Facility Information

[REDACTED]

Department

Name	Address	Phone	Fax
------	---------	-------	-----

[REDACTED]			
------------	--	--	--

[page 13 of 18]
Study Result

Verified

Comparison: +134

Indication: Lung cancer restaging.

Technique: CT imaging was performed of the chest, abdomen, and pelvis following the uncomplicated administration of intravenous contrast (Isovue-300, 150 mL at 3 mL/sec). Iodinated contrast was used due to the indications for the examination. If IV contrast material had not been administered, the likelihood of detecting abnormalities relevant to the patient's condition would have been substantially decreased. The most recent serum creatinine is 1.0 mg/dL. Coronal reformatted images of the abdomen and pelvis and axial MIP images of the chest were generated and reviewed to improve anatomic localization and optimize lesion detection.

Findings: The central airways are patent and normal in caliber. There is a 6.6 x 6.0 cm low-attenuation mass within the right hemithorax which appears slightly decreased in size compared to prior (previously measuring 7.0 x 6.7 cm). There is interval decrease in size of peripheral solid components. No new pulmonary nodules identified. Negative for pleural effusion.

The thyroid gland is normal in appearance. Standard 3 vessel aortic arch. The thoracic aorta is normal in caliber. The heart is normal in size. The main pulmonary artery is normal in caliber.

No axillary lymphadenopathy. There is a low-attenuation right hilar lymph node measuring 2.0 x 1.5 cm (previously 2.2 x 1.8 cm). No mediastinal lymphadenopathy.

In the abdomen there is no intraperitoneal free air. The abdominal aorta is normal in caliber. Major branch vessels appear patent.

The liver is normal in size and contour. No focal lesions identified. The portal and hepatic veins appear patent. No intrahepatic biliary ductal dilation. The gallbladder is not visualized. The pancreas is normal in appearance. Small splenule noted near the hilum of the spleen. Tiny low attenuation splenic lesions appear unchanged.

There is a 1.7 x 1.3 cm low-attenuation lesion in the left adrenal gland (previously measuring 1.9 x 1.9 cm). The right adrenal gland is normal in size and contour. The kidneys enhance symmetrically. No focal renal lesions identified. The ureters are normal in caliber. The bladder is normal in appearance.

The small bowel is normal in caliber. Status post ileostomy in the right lower quadrant. Status post extended right colectomy with left upper quadrant colonic mucous fistula again noted. In a bladder there is no leg both small and inguinal the retroperitoneal lymph nodes in appear unchanged from prior.

No aggressive lytic or sclerotic osseous lesions.

[page 14 of 18]
Impression:

1. Interval decrease in size of the right lung mass, right hilar lymphadenopathy, and left adrenal lesion consistent with favorable response to treatment.

I have reviewed the images and concur with the above findings.

Imaging

CT chest with contrast (Order [REDACTED]) [Imaging Information](#)

Result History

CT chest with contrast (Order [REDACTED]) [Order Result History Report](#)

Signed by

Signed	Date/Time	Phone	Pager
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]

Exam Information

Status	Exam Begun	Exam Ended
[REDACTED]	[REDACTED]	[REDACTED]

PACS Images

[Show images for CT chest with contrast](#)

External Result Report

[External Result Report](#)

Encounter

[View Encounter](#)

CT chest with contrast

Status: Final result

Supplies

No case/log ID found

CT chest with contrast

Date: [REDACTED] [+197](#)

Imaging

Department: [REDACTED]

Order:

Ordering/Aut [REDACTED]

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]

Order Details

Frequency	Duration	Priority	Order Class
None	None	ONCE	Normal

Collection Information

+197 [REDACTED]

[page 15 of 18]
Study Result

Verified

Comparison: [REDACTED] +79

Indication: Lung cancer restaging.

Technique: CT imaging was performed of the chest, abdomen, and pelvis following the uncomplicated administration of intravenous contrast (Iovue-300, 150 mL at 3 mL/sec). Iodinated contrast was used due to the indications for the examination. If IV contrast material had not been administered, the likelihood of detecting abnormalities relevant to the patient's condition would have been substantially decreased. The most recent serum creatinine is 1.0 mg/dL. Coronal reformatted images of the abdomen and pelvis and axial MIP images of the chest were generated and reviewed to improve anatomic localization and optimize lesion detection.

Findings:**Chest:**

There is a large centrally necrotic pleural-based mass of the right upper lobe (image 108) which measures 7.0 x 6.7 cm compared to 8.1 x 7.3 cm previously. There is a stable soft tissue component along the medial and posterior aspect of the mass as well as along the lateral aspect of the mass with possible pleural and intercostal muscular involvement. No new pulmonary nodules or focal airspace disease evident. The pleural spaces are clear. There is an ipsilateral enlarged right hilar lymph node which measures 2.2 x 1.8 cm compared to 2.5 x 2.1 cm previously (image 118). No new hilar, mediastinal, axillary, or supraclavicular adenopathy evident.

The heart size is within normal limits without pericardial effusion. The thoracic aorta is normal in course and caliber without dissection. Conventional arch anatomy identified. The main pulmonary artery is normal in caliber without focal filling defect. No endobronchial lesions or central airway stenosis identified.

Abdomen/pelvis:

Enhanced images of the liver, spleen, pancreas, kidneys, and right adrenal gland are unremarkable. There is a centrally necrotic nodule of the left adrenal gland that measures 1.9 x 1.9 cm compared to 2.7 x 2.4 cm previously (image 16).

The stomach has a normal appearance. Right lower quadrant ileostomy and left upper quadrant colonic mucous fistula again noted. No focal or diffuse bowel wall thickening or evidence of bowel obstruction.

The bladder maintains a smooth contour. The prostate gland is normal in size. Scattered pelvic phleboliths noted.

No ascites or pneumoperitoneum. No pneumatosis or portal venous gas.

Subcentimeter lymph nodes noted throughout the mesentery and retroperitoneum. No new abdominal or pelvic lymphadenopathy identified.

Abdominal aorta the normal in course and caliber without dissection.

[page 16 of 18]
Origins and visualized segments of the celiac, mesenteric, renal, and iliac arteries are patent. The portal venous system and IVC are patent.

No fractures or aggressive osseous lesions identified.

Impression:

Interval response to treatment characterized by decrease in size of right upper lobe pulmonary mass, right hilar adenopathy, and left adrenal

metastatic lesion.

The preliminary report (critical or emergent communication) was reviewed prior to this dictation and there are no substantial differences between the preliminary results and the impressions in this final report.

I have reviewed the images and concur with the above findings.

Imaging

CT abdomen pelvis with contrast [REDACTED] Imaging Information

Result History

+134

CT abdomen pelvis with contrast [REDACTED] Order Result History Report

Signed by

+134

Signed [REDACTED] Date/Time [REDACTED] Phone [REDACTED] Pager [REDACTED]

Exam Information

+134

Status
Final [99]

Exam
Begun

Exam
Ended

PACS Images

+133

+133

Show images for CT abdomen pelvis with contrast

External Result Report

External Result Report

Encounter

View Encounter

CT abdomen pelvis with contrast

Status: Final result

Supplies

No case/log ID found

CT abdomen pelvis with contrast (Order

Date: [REDACTED] +133

Department: [REDACTED]

Ordering/Aut [REDACTED]

Imaging

Order: [REDACTED]

[page 17 of 18]
CT abdomen pelvis with contrastStatus: **Final result****Study Result**

CT abdomen and pelvis with IV contrast

Comparison: CT of the chest, abdomen, and pelvis of [REDACTED] +1099

Indication: 162.9 Malignant neoplasm of bronchus and lung, unspecified site, lung cancer. Surgical history includes right upper lobectomy, left adrenalectomy, partial small bowel resection, and right hemicolectomy.

Technique: CT imaging was performed of the abdomen and pelvis following the uncomplicated administration of intravenous contrast (Isovue-300, 150 mL at 3 mL/sec). Iodinated contrast was used due to the indications for the examination, to improve disease detection and further define anatomy. The most recent serum creatinine is 1.2 mg/dL. Coronal reformatted images were generated and reviewed.

Findings:

Scarring versus atelectasis in the peripheral right lung base. Left lung is clear.

Liver, spleen, pancreas, and right adrenal gland appear within limits of normal. There are postoperative changes of the left adrenal gland with no new soft tissue mass/nodularity identified. The gallbladder is filled with stones dependently. No gallbladder wall thickening or pericholecystic fluid appreciated. No intrahepatic or extrahepatic biliary ductal dilatation identified. No evidence of renal stone or hydroureteronephrosis identified.

The abdominal aorta is normal in caliber, and its proximal branches are patent. There has been prior right hemicolectomy. Small bowel resection is also noted. There is a right lower quadrant ileostomy. No retroperitoneal mass or adenopathy identified. There is no aggressive osseous lytic or destructive process identified.

Impression:

1. No new mass or adenopathy identified within the abdomen or pelvis.
2. Stable postoperative changes of left adrenalectomy, partial small bowel resection, and right hemicolectomy.

ImagingCT abdomen pelvis with contrast (Order [REDACTED]) Imaging Information
+1281**Result History**CT abdomen pelvis with contrast (Order [REDACTED]) Order Result History Report
+1281**Signed by**

Signed	Date/Time	Phone	Pager
[REDACTED]			

+1281

[page 18 of 18]
Exam Information

Status
Final [99]

Exam
Begun

Exam
Ended

+1281

+1281

PACS Images

Show images for CT abdomen pelvis with contrast

External Result Report

External Result Report

Encounter

View Encounter

CT abdomen pelvis with contrast

Status: **Final result**

Supplies

No case/log ID found

CT abdomen pelvis with contrast

+1281

Imaging

Released By

Date:

Authorizing:

Department:

Order

Order Information

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Order Details

+1281

+1281

Frequency
None

Duration
None

Priority
STAT

Order Class
Ancillary Performed

Associated Diagnoses

Lung cancer

Collection Information

Collected

+1281

Resulting Agency:

Order Provider Info

Office

phone

Pager/beeper: E mail

Ordering User

Authorizing Provider

Attending Provider

Billing Provider

Reprint Requisition

CT ABDOMEN PELVIS WITH CONTRAST

+1281

Source: NCI Genomic Data Commons file 8bb3af93-5091-4bc1-964e-35ae7fe1f84b (ER0260 ER-AD3D Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).